Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4O2, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4O2-01A (Primary Tumor).

Collection 1

FINAL DIAGNOSIS:

PARTS 1

AND 2: PARIETAL PLEURA, RIGHT, BIOPSY -
DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE.

COMMENT:

The tumor cells are positive for calretinin, WT-1, D2-40 and cytokeratin 5/6 and negative for CEA, Ber-EP4, B72.3 and TTF-1. These results support the above diagnosis.

ICD-O-3

mesothelioma, epithelioid, Nos. 9052/3

Site: pleura, nos C38.4

hw
9/25/12

Source: NCI Genomic Data Commons file bec21670-8c08-452a-a4b1-5ce91e615c00 (TCGA-LK-A4O2.D4751900-6378-445D-B82E-D9459A292CBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).